Gene-level copy-number profile of tumor specimen TCGA-3B-A9I3-01A from TCGA case TCGA-3B-A9I3, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 62.9 years (22,985 days).
Specimen TCGA-3B-A9I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.faaf8654-8341-4fbc-8a9b-8add4db80295.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9I3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7da15dc7-f900-485b-a6a5-81f09ac805d6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 20; copy number 2: 5,246; copy number 3: 33,755; copy number 4: 20,152; copy number 5: 576; copy number 6: 23; copy number 7: 34; copy number 8: 8; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9I3-01A-11D-A38Y-01): tumor purity 0.4, ploidy 1.62, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:36,626,015–36,626,138, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 43 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:177,351,562–177,437,880, 1 gene, copy number 7: LINC01645.
- chr4:10,199,823–10,295,579, 8 genes, copy number 8: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,216,416–77,216,878, 1 gene, copy number 9: AC008638.3.
- chr8:139,508,701–139,508,971, 1 gene, copy number 7: AC090093.1.
- chr11:50,409,042–55,555,419, 32 genes, copy number 7: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
